MMRF case MMRF_2091 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ea87a825-74ed-4454-b4c0-45ccb0a3e378

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.7 years (18,143 days); ISS stage: II; Days to last known disease status: 897 days (2.5 years); Days to last follow up: 897 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 142 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 144 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 50 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 5.1 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 30 g/L; Total Protein 9.9 g/dL; Glucose 6.44 mmol/L.
- Day 85 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 0.98 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 3.47 mmol/L.
- Day 168 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.77 mg/dL; Lactate Dehydrogenase 5.68 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 0.52 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 1.07 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 4.73 mmol/L.
- Day 246 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 9.44 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.63 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 330 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.21 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 4.18 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.905 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.52 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 3.96 mmol/L.
- Day 533 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 8.53 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.52 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.18 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 8.09 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.31 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 4.35 mmol/L.
- Day 813 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.67 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.4 mmol/L.
- Day 897 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.83 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -20: Weight: 109 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2091_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2091_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
